Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A4NN, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A4NN-01A (Primary Tumor).

ICD-6-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0

9/12/2012

TISSUE DESCRIPTION:

A1 B1 B2 C1 C2 C3 C4 C5 C6 C7 C8 C9 C10 C11 C12 C13 C14
C15 C16 C17

Liver segment V and VI (245 grams; 10.3 x 9.8 x 4.5 cm), gallbladder
(6.5 x 2.7 x 1.3 cm), and choledochal lymphadenectomy tissue (2
lymph nodes 2.5 x 1.0 x 0.8 cm and 2.4 x 0.6 x 0.6 cm).

DIAGNOSIS:

Liver, segments V and VI, resection: Grade 3 (of 4) hepatocellular
carcinoma forming a 7.4 x 5.7 x 5.4 cm mass. The surgical margin is
free of tumor by 3.0 cm. The histology of the surrounding
non-neoplastic liver will be reported in an addendum.

Gallbladder, cholecystectomy: Chronic cholecystitis. No gallstones
present.

Lymph nodes, choledochal, excision: Multiple (2) lymph nodes are
negative for tumor.

HI/PAI Discrepancy		☒

Source: NCI Genomic Data Commons file f377cf33-6400-4ae0-aa4e-3bc888929481 (TCGA-DD-A4NN.16053CE8-B3B1-4925-AEAA-5B118E1C2E45.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).